Somatic mutation profile of tumor specimen TCGA-61-2109-01A (aliquot TCGA-61-2109-01A-01W-0722-08) from TCGA case TCGA-61-2109, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 40.8 years (14,900 days).
Specimen TCGA-61-2109-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a949c913-66e1-4bd1-aff9-246c240e9c23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2109-11A (Solid Tissue Normal), aliquot TCGA-61-2109-11A-01W-0723-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5962b059-7546-485a-9882-1aa865955bf3

The open-access MAF lists 79 somatic variants for this specimen: 64 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 13, Frame Shift Del 5, Nonsense Mutation 3, Intron 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.2055G>A p.W685* | Nonsense Mutation (SNP) | VAF 68/157 reads (43%) | catalogued as COSV66071579; called by muse, mutect2, varscan2
- ADAMTS14 | c.814G>C p.V272L | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.38); catalogued as COSV64607204; called by mutect2, varscan2
- ALG1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as COSV99275617; called by muse, mutect2, varscan2
- ANKRD55 | c.1698C>A p.N566K | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as rs878856662, COSV61951369; called by muse, mutect2, varscan2
- APIP | c.563G>C p.C188S | Missense Mutation (SNP) | VAF 229/530 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV99551499; called by muse, mutect2, varscan2
- AWAT2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52144848; called by muse, mutect2, varscan2
- BACH2 | c.1583A>C p.Y528S | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV57611292; called by muse, mutect2, varscan2
- C12orf29 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV58357208; called by muse, mutect2, varscan2
- CCDC39 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); catalogued as COSV56495144; called by muse, mutect2
- CHD4 | c.3085G>T p.G1029C (on ENST00000357008 / NM_001363606.2; = p.G1042C on NM_001273.5) | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58912430; called by muse, mutect2, varscan2
- CSK | c.1171-1G>T p.X391_splice | Splice Site (SNP) | VAF 37/48 reads (77%) | catalogued as COSV54976368; called by muse, mutect2, varscan2
- CSMD2 | c.6497G>T p.G2166V | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53971478; called by muse, mutect2, varscan2
- EPHB1 | c.350C>A p.T117N | Missense Mutation (SNP) | VAF 113/256 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101213615, COSV67673309; called by muse, mutect2, varscan2
- ESYT1 | c.1845G>C p.W615C | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.188); catalogued as COSV57277097, COSV99919629; called by muse, mutect2, varscan2
- EXOC5 | c.1091T>A p.I364N | Missense Mutation (SNP) | VAF 80/94 reads (85%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.883); catalogued as COSV61772515; called by muse, mutect2, varscan2
- FAT1 | c.4659C>G p.S1553R | Missense Mutation (SNP) | VAF 80/91 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV71673336, COSV71676263; called by muse, varscan2
- FMO3 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100882417; called by muse, mutect2
- FOXD3 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64380007; called by muse, mutect2
- GAD2 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52170323; called by muse, mutect2, varscan2
- GOSR1 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 189/233 reads (81%) | SIFT tolerated (0.15); PolyPhen benign (0.348); catalogued as COSV56721169; called by muse, mutect2, varscan2
- GPRIN3 | c.928A>C p.K310Q | Missense Mutation (SNP) | VAF 96/129 reads (74%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV60886689; called by muse, mutect2, varscan2
- GSK3A | c.1200C>G p.H400Q | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55901020; called by muse, mutect2, varscan2
- HIVEP2 | c.1729T>C p.F577L | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV50083939; called by muse, mutect2, varscan2
- HSPA12B | c.350G>T p.S117I | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV54769525; called by muse, mutect2, varscan2
- IPO13 | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 144/283 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV64895371; called by muse, mutect2, varscan2
- ITSN1 | c.3584G>C p.G1195A | Missense Mutation (SNP) | VAF 168/436 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66086814; called by muse, mutect2, varscan2
- KLHL24 | c.1779C>G p.Y593* | Nonsense Mutation (SNP) | VAF 33/157 reads (21%) | catalogued as COSV54429177; called by muse, mutect2, varscan2
- KPRP | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs201034376, COSV64221256, COSV64221349; called by muse, mutect2, varscan2
- LRRTM4 | c.679C>G p.R227G | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101297775, COSV69143045; called by muse, mutect2, varscan2
- MACF1 | c.15515A>G p.N5172S (on ENST00000372915; = p.N3105S on NM_012090.5) | Missense Mutation (SNP) | VAF 50/122 reads (41%) | catalogued as COSV57148578; called by muse, mutect2, varscan2
- MAP3K7 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 103/219 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65234169, COSV65236014; called by muse, mutect2, varscan2
- MARCHF2 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 37/75 reads (49%) | catalogued as COSV53107052; called by muse, mutect2, varscan2
- MEOX1 | c.668G>T p.R223M | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100233710, COSV59355621; called by muse, mutect2
- METTL15 | c.178T>G p.S60A | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as COSV57724592; called by muse, mutect2, varscan2
- MYH11 | c.1916T>G p.L639R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV55572671; called by muse, mutect2, varscan2
- MYH4 | c.2495C>A p.P832H | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV99700703; called by muse, mutect2
- NACA | c.234+2T>A p.X78_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV63273579; called by muse, varscan2
- OR2T5 | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 106/565 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751102516, COSV63540989; called by muse, mutect2, varscan2
- PDLIM7 | c.1271C>G p.T424S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63082332; called by muse, varscan2
- PIGO | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs371317684; called by muse, mutect2, varscan2
- PIK3R4 | c.1826G>A p.G609D | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as COSV63241917, COSV63244371; called by muse, mutect2, varscan2
- POT1 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs947005337, CM144566, COSV62935384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN7 | c.389C>T p.P130L (on ENST00000495688; = p.P169L on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100459742; called by muse, mutect2
- SAMD9 | c.2276G>C p.R759T | Missense Mutation (SNP) | VAF 90/591 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66077972; called by muse, mutect2, varscan2
- SRSF11 | c.1028G>C p.R343T | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV63937948; called by muse, mutect2, varscan2
- ST6GAL2 | c.1333A>G p.M445V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | PolyPhen benign (0.222); catalogued as COSV62418401; called by muse, mutect2, varscan2
- STK36 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.274); catalogued as COSV99831169; called by muse, mutect2
- TCF20 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59496841; called by muse, mutect2, varscan2
- TMEM109 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV50027568; called by muse, mutect2, varscan2
- USH2A | c.12731A>G p.N4244S | Missense Mutation (SNP) | VAF 93/277 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV56445156; called by muse, mutect2, varscan2
- USP15 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV99738954; called by muse, mutect2, varscan2
- WNT7B | c.461C>G p.A154G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV59752660; called by muse, mutect2
- ZNF20 | c.611G>C p.C204S | Missense Mutation (SNP) | VAF 200/444 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62000700; called by muse, mutect2, varscan2
- ZNF215 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 554/680 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs779257793, COSV53495444, COSV99549246; called by muse, mutect2, varscan2
- ZNF43 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 112/288 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100731750, COSV61685059; called by muse, mutect2, varscan2
- ZNF45 | c.1355G>C p.G452A | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV54194959; called by muse, varscan2
- ZNF708 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV63609049; called by muse, mutect2, varscan2
- ALOX12 | c.1781_1790del p.S594* | Frame Shift Del (DEL) | VAF 16/26 reads (62%) | called by mutect2, pindel, varscan2
- DCDC2B | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ENTPD6 | c.47_48insCTACTGTA p.F17Yfs*16 | Frame Shift Ins (INS) | VAF 8/192 reads (4%) | called by muse*, mutect2
- IMMP1L | c.116_119del p.P39Qfs*30 | Frame Shift Del (DEL) | VAF 55/182 reads (30%) | called by mutect2, pindel, varscan2
- KPNA3 | c.1000_1004del p.L334Ifs*9 | Frame Shift Del (DEL) | VAF 201/248 reads (81%) | called by mutect2, pindel, varscan2
- TP53 | c.918_919del p.A307Tfs*29 | Frame Shift Del (DEL) | VAF 98/157 reads (62%) | called by mutect2, pindel, varscan2
- ZNF708 | c.1206del p.K403Sfs*10 | Frame Shift Del (DEL) | VAF 55/160 reads (34%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.5544G>C p.V1848= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV60933388; called by muse, mutect2, varscan2
- BIRC6 | c.4893A>C p.L1631= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV70195417, COSV70207251; called by muse, mutect2, varscan2
- DAW1 | c.570A>G p.T190= | Silent (SNP) | VAF 58/714 reads (8%) | catalogued as COSV100006037; called by muse, mutect2
- KALRN | c.2451G>C p.R817= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV53782424, COSV99564738; called by muse, mutect2, varscan2
- LTBP1 | c.2826C>T p.C942= (on ENST00000404816 / NM_206943.4; = p.C616= on NM_000627.4) | Silent (SNP) | VAF 96/281 reads (34%) | catalogued as COSV63199055; called by muse, varscan2
- MEIOC | c.2160T>C p.P720= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as rs767219883, COSV63441698; called by muse, mutect2, varscan2
- NEFM | c.1113G>A p.R371= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs781549347, COSV55335378; called by muse, mutect2, varscan2
- PCDHB3 | c.2097G>A p.S699= | Silent (SNP) | VAF 26/279 reads (9%) | catalogued as rs1328549301, COSV50635050; called by muse, mutect2
- PPP1R3A | c.1299C>G p.G433= | Silent (SNP) | VAF 189/539 reads (35%) | catalogued as COSV52894493; called by muse, mutect2, varscan2
- RYR3 | c.1191G>A p.L397= | Silent (SNP) | VAF 252/576 reads (44%) | catalogued as COSV66810712; called by muse, mutect2, varscan2
- SBF2 | c.4758G>A p.E1586= | Silent (SNP) | VAF 78/99 reads (79%) | catalogued as rs770533275, COSV56313650; called by muse, mutect2, varscan2
- SEMA4A | c.933C>T p.P311= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV61774061; called by muse, mutect2, varscan2
- SPIN2A | c.753C>T p.V251= | Silent (SNP) | VAF 66/220 reads (30%) | catalogued as COSV66520822; called by muse, mutect2, varscan2
- LRRC71 | c.1563+84G>A | Intron (SNP) | VAF 55/162 reads (34%) | catalogued as COSV100168416; called by muse, mutect2, varscan2
- TTBK2 | c.823-6880del | Intron (DEL) | VAF 44/144 reads (31%) | called by pindel, varscan2
